FM case AD9201 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Vagina.
https://portal.gdc.cancer.gov/cases/dc818c51-a82f-4afa-8a89-694f509ffdad

Female, 41.1 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the vagina; primary biopsied or resected from the vagina. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
